Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9R0, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9R0-01A (Primary Tumor).

SPECIMEN

- A. Right side lymph node
- B. Right ureteric resection margin
- C. Bladder and prostate

CLINICAL DETAILS

Invasive bladder cancer.

MACROSCOPY

- A. Fat and lymph node measuring 45 x 20 x 15 mm.
1-3 = ? One lymph node in each
- B. A piece of tube measuring 3 mm.
- C. Bladder and prostate measuring 130 x 80 x 60 mm. There is a huge tumour occupying most of the bladder wall. The tumour is centred posterior and extends bilaterally to the lateral wall. The tumour invades through the bladder wall with extensive peritoneal involvement. The tumour is within 1 mm of the left lateral circumferential resection margin (closest). There is a massive tumour superior bulging into the peritoneum. The maximum tumour dimension is 130 mm. The tumour abuts the prostate but does not appear to involve the prostate. The prostate shows a minor degree of nodular hyperplasia.
1 = Urethral distal resection margin, 2 = Left prostate, 3 = Right prostate, 4 = Right prostate, 5 = Posterior urethral plus trigone, 6 = Tumour edge of prostate, 7-8 = Anterior bladder wall, 9 = Left lateral wall circumferential resection margin, 10 = Posterior wall with peritoneum involvement, 11 = Right lateral wall circumferential resection margin, dome and peritoneum, 12 = ? Left ureter, 13 = ? Right ureter plus vas, 14 = Tumour

MICROSCOPY

- A. One lymph node with reactive changes and no tumour; most of the sample is fat.
- B. This sample of ureter does not have any visible urothelium.
- C. The tumour identified is poorly differentiated grade 3 urothelial carcinoma. Tumour invades the full thickness of the bladder wall and beyond into adipose tissue and the peritoneal surface. The tumour is also present at the surgical resection margin on the right lateral aspect. Though the tumour involves the trigone there is no invasion of the prostate gland. Background urothelium is normal. The prostate shows nodular hyperplasia and focal necrosis with granulomatous response. The samples taken from the ureterics do not show urothelium.

Summary:

Cystoprostatectomy specimen; High grade infiltrating urothelial carcinoma G3 pT3b pN0 R1.

Though recorded as pN0, only one small node has been sampled and no formal dissection presented for examination.

Pathologists

CONSULTANT

ICD-03

Carcinoma, urothelial NOS
8120/3

Site: Bladder, posterior wall
C67.4

9/25/14

Source: NCI Genomic Data Commons file efb042b8-6753-4122-b14d-fe03f97a4b8f (TCGA-ZF-A9R0.A69288AE-85B5-4041-A601-A7ACDBCBBEB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).